Somatic mutation profile of tumor specimen TCGA-J4-A83I-01A (aliquot TCGA-J4-A83I-01A-11D-A364-08) from TCGA case TCGA-J4-A83I, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.6 years (23,240 days).
Specimen TCGA-J4-A83I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b11a4cf3-9a66-41c3-be1f-a0b8f1558c8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J4-A83I-10B (Blood Derived Normal), aliquot TCGA-J4-A83I-10B-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffc29816-b348-486f-bc73-98d8935681f9

The open-access MAF lists 26 somatic variants for this specimen: 15 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 9, Frame Shift Ins 2, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL11A1 | c.512T>A p.V171E | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100616458; called by muse, mutect2, varscan2
- EPB41L1 | c.1412G>A p.G471E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1446296849, COSV99150827; called by muse, mutect2, varscan2
- FAM71C | c.155A>G p.Q52R | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746189188, COSV100175742; called by muse, mutect2, varscan2
- FANCB | c.481G>T p.V161F | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV100146530; called by muse, mutect2, varscan2
- FILIP1 | c.113A>C p.K38T | Missense Mutation (SNP) | VAF 81/180 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.401); catalogued as COSV99384757; called by muse, mutect2, varscan2
- FZD6 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as rs762407732, COSV100708372; called by muse, mutect2, varscan2
- MXRA5 | c.6317C>G p.T2106R | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54242882, COSV99476892; called by muse, mutect2, varscan2
- ORMDL1 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100360550; called by muse, mutect2
- PASK | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 55/105 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV99299374; called by muse, mutect2, varscan2
- SLC12A5 | c.1168G>A p.V390M (on ENST00000454036 / NM_001134771.2; = p.V367M on NM_020708.5) | Missense Mutation (SNP) | VAF 81/190 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs778801242, COSV54795394; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SRRM4 | c.1474C>A p.P492T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs770519410, COSV99938481; called by muse, varscan2
- ZW10 | c.129C>G p.S43R | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.033); catalogued as COSV99562663; called by muse, mutect2, varscan2
- EXOSC10 | c.306dup p.V103Sfs*3 | Frame Shift Ins (INS) | VAF 64/198 reads (32%) | called by mutect2, pindel, varscan2
- OR4P4 | c.10dup p.S4Kfs*3 | Frame Shift Ins (INS) | VAF 55/99 reads (56%) | called by mutect2, pindel, varscan2
- XAGE2 | c.267G>T p.K89N | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2
- CYP4F3 | c.936G>A p.K312= | Silent (SNP) | VAF 6/136 reads (4%) | catalogued as COSV99658151; called by muse, mutect2
- DDX46 | c.2593T>C p.L865= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as rs1195539427, COSV62801717; called by muse, mutect2, varscan2
- KIF5A | c.300G>A p.L100= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV99672944; called by muse, mutect2, varscan2
- MELTF | c.1134G>A p.K378= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs1387821174, COSV99586158; called by muse, mutect2
- MFAP3L | c.1062C>G p.P354= | Silent (SNP) | VAF 39/109 reads (36%) | catalogued as COSV100852674, COSV64373425; called by muse, mutect2, varscan2
- MMP17 | c.261G>A p.Q87= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100861925; called by muse, mutect2, varscan2
- PCDHB6 | c.2082G>A p.S694= | Silent (SNP) | VAF 83/223 reads (37%) | catalogued as rs558040784, COSV50741551; called by muse, mutect2, varscan2
- RNF20 | c.1404A>G p.Q468= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV101206524; called by muse, mutect2, varscan2
- TMEM132D | c.801C>T p.I267= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs907461232, COSV101400002, COSV70594780; called by muse, mutect2, varscan2
- ARRDC1 | chr9:137615845 C>T | 3'Flank (SNP) | VAF 22/59 reads (37%) | catalogued as rs111459138; called by muse, mutect2, varscan2
- DCHS2 | n.1575G>A | RNA (SNP) | VAF 17/46 reads (37%) | catalogued as COSV59719448; called by muse, mutect2, varscan2
